Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3SZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3SZ-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Specimen(s) Received

1. Parathyroid: Right Upper/QS
2. Lymph node: Right paratracheal node
3. Thyroid: Total thyroid (stitch marks upper pole right lobe)

HPA Discrepancy		X

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy
2. No pathological diagnosis: Lymph node (right paratracheal) excisional biopsy
3. Multifocal papillary carcinoma, dominant widely invasive mixed classical and Warthin-like variant with focal tall cell (<10%) and hobnail cell change (<20%), 2.6 cm, right lobe; underlying chronic lymphocytic thyroiditis: Thyroid
- No pathological diagnosis: Parathyroid, left intrathyroidal
No pathological diagnosis: Lymph nodes, 2, isthmic
No pathological diagnosis: Lymph node, 1, left perithyroidal
- Total thyroidectomy specimen

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	4.4 cm
	2.8 cm
	2.1 cm
	Left lobe:
	5.0 cm
	2.3 cm
	1.3 cm
	Isthmus +/- pyramidal lobe:
	4.0 cm
	1.0 cm
	0.7 cm
Specimen Weight:	24.1 g
Tumor Focality:	Multifocal, bilateral

----- DOMINANT TUMOR -----

ICD-O3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

4-3-12
RP

[page 2 of 3]
Surgical Pathology Consultation Report

Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.6cm
Additional dimension: 1.6 cm
Additional dimension: 1.6 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, Warthin-like variant
Papillary carcinoma, other variant: with focal tall cell (<10%) and hobnail cell change (<20%)
Classical (papillary) architecture
Classical cytomorphology
Tall cell cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 0.2cm
Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: None
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 4
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Thyroiditis, other: chronic lymphocytic thyroiditis
Parathyroid gland(s), within normal limits
Other: additional 0.1 cm follicular variant papillary microcarcinoma, left lobe

*Pathologic Staging is based on AJCC/UICC TNM, . Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "right upper parathyroid" consists of a tiny piece of tissue that measures 0.3 x 0.3 x 0.2 cm. It is frozen for intraoperative consultation.

1A frozen tissue resubmitted

[page 3 of 3]
Surgical Pathology Consultation Report

2. The specimen labeled with the patient's name and as "right paratracheal node" consists of one lymph node that measures 0.4 x 0.4 x 0.3 cm.

2A bisected and submitted in toto

3. The specimen labeled with the patient's name and as "total thyroid stitch marks upper pole right lobe" consists of a thyroid gland that is oriented with a stitch marking the right upper pole and weighs 24.1 g. The right lobe measures 4.4 cm SI x 2.8 cm ML x 2.1 cm AP, the left lobe measures 5.0 cm SI x 2.3 cm ML x 1.3 cm AP and the isthmus measures 4.0 cm SI x 1.0 cm ML x 0.7 cm AP. The external surfaces have fibrous adhesions and are painted with blue dye. No parathyroid glands or no lymph nodes are identified grossly. The superior mid right lobe contains one well delineated nodule that measures 2.6 cm SI x 1.6 cm ML x 1.6 cm AP. A second tiny nodule is identified on the mid pole of the left lobe measuring 0.5 SI x 0.4 ML x 0.5 cm AP. The cut surface of both nodules is red-tan in color and has a soft and flabby consistency. The remainder of the thyroid tissue is grossly unremarkable. Sections of right nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

3A-1 right lobe, superior to inferior

3J isthmus

3K-Q left lobe, superior to inferior

Quick Section Diagnosis

1. Parathyroid, right upper: Parathyroid tissue.

Source: NCI Genomic Data Commons file 461c3e13-6784-4f61-bef9-4a5e62df843b (TCGA-EM-A3SZ.EB2DC574-B401-44C0-9C5A-A9353A5ABF75.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).